Surgical pathology report (de-identified scan), TCGA case TCGA-85-8355, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-8355-01A (Primary Tumor).

[page 1 of 3]
TCGA Pathology Reports

[REDACTED]		Case ID	Gross Description	Microscopic Description
[REDACTED]		[REDACTED]	Lung lobe with the tumour of 2.5 x 1.8 cm; lymph nodes of the hilus are soft, hyperemic; surgical margins are free of tumor.	Bronchus tumour - squamous carcinoma with a tendency to keratinization, G2. Separately fragment of the bronchus wall (surgical margins) of normal structure. Twelve examined lymph nodes demonstrated anthracosis, sinus histiocytosis.

[page 2 of 3]
Diagnosis Details	Comments	Formatted Path Report
Tumor Features: Unknown, Tumor Extent: Localized, NOS , Venous Invasion: Absent, Margins: Absent, Treatment Effect:		LUNG TISSUE CHECKLIST Specimen type: Lobectomy Tumor site: Lung Tumor size: 1.8 x 0 x 2.5 cm Histologic type: Squamous cell carcinoma Histologic grade: Moderately differentiated Tumor extent: Not specified Other tumor nodules: Not specified Lymph nodes: 0/12 positive for metastasis (Peribronchial lymph nodes 0/12) Lymphatic invasion: Not specified Venous invasion: Absent Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: Left- upper

[page 3 of 3]
OpenClinica ID	Excision Date	Laterality
		Left-upper

Source: NCI Genomic Data Commons file 5a030d8c-fbc4-4c7d-95d5-17559f712b39 (TCGA-85-8355.AA408276-FFDE-4EA0-A510-3035F653F039.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).